Somatic mutation profile of tumor specimen TCGA-AQ-A04H-01B (aliquot TCGA-AQ-A04H-01B-11D-A10M-09) from TCGA case TCGA-AQ-A04H, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 61.7 years (22,539 days).
Specimen TCGA-AQ-A04H-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 777ce2b1-0cd8-41a4-b4f3-fd0863e2ccd4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AQ-A04H-10A (Blood Derived Normal), aliquot TCGA-AQ-A04H-10A-01D-A10M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c934f878-81be-4dbc-97aa-63e9dbcfddd3

The open-access MAF lists 67 somatic variants for this specimen: 51 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 45, Silent 16, Nonsense Mutation 3, Splice Site 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CA4 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs121434552, CM072913, COSV56282434, COSV99039723; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OTX2 | c.265C>T p.R89* (on ENST00000408990 / NM_172337.3; = p.R97* on NM_021728.4) | Nonsense Mutation (SNP) | VAF 50/107 reads (47%) | catalogued as rs104894464, CM051593, CM104945, COSV59766659; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.590T>G p.V197G | Missense Mutation (SNP) | VAF 112/155 reads (72%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM994748, COSV52661145, COSV52810143, COSV53120183; called by muse, mutect2, varscan2
- ADGRG2 | c.2454G>T p.K818N (on ENST00000379869 / NM_001079858.3; = p.K815N on NM_005756.4) | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as COSV61341743; called by muse, mutect2, varscan2
- AGO2 | c.2149T>A p.C717S | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.271); catalogued as COSV55053479; called by muse, mutect2, varscan2
- AMPD1 | c.1191+2T>C p.X397_splice | Splice Site (SNP) | VAF 49/140 reads (35%) | catalogued as COSV62419483; called by muse, mutect2, varscan2
- ANKRD12 | c.230A>G p.D77G | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV50854150; called by muse, mutect2, varscan2
- ATP11A | c.94G>T p.E32* | Nonsense Mutation (SNP) | VAF 19/44 reads (43%) | catalogued as COSV52126354, COSV99368844; called by muse, mutect2, varscan2
- CDS2 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 96/285 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.786); catalogued as rs576280057, COSV66897950; called by muse, mutect2, varscan2
- CEP290 | c.7420G>A p.V2474I | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV58357148; called by muse, mutect2, varscan2
- CLDN6 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as rs766749711, COSV58510860; called by muse, mutect2, varscan2
- COL22A1 | c.2920G>A p.A974T | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.042); catalogued as COSV57364021; called by muse, mutect2, varscan2
- CSMD1 | c.5852G>A p.R1951H (on ENST00000520002; = p.R1950H on NM_033225.6) | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (1); PolyPhen possibly damaging (0.885); catalogued as rs752278123, COSV59331265, COSV59389613; called by muse, mutect2, varscan2
- DGKD | c.1663G>A p.D555N (on ENST00000264057 / NM_152879.3; = p.D511N on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as rs753381810, COSV51115227; called by muse, mutect2, varscan2
- DGKG | c.1720G>A p.V574I | Missense Mutation (SNP) | VAF 112/168 reads (67%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV53974006; called by muse, mutect2, varscan2
- DSEL | c.1598C>T p.A533V | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as rs373569592; called by muse, mutect2, varscan2
- EPS8 | c.1508A>G p.H503R | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV55537421; called by muse, mutect2, varscan2
- FLRT2 | c.1405C>T p.R469C | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs755278961, COSV58142064, COSV58143564; called by muse, mutect2, varscan2
- HAND2 | c.339G>T p.Q113H | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV100854167; called by muse, mutect2
- KCNB1 | c.2321C>T p.P774L | Missense Mutation (SNP) | VAF 50/222 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.184); catalogued as COSV65571281; called by muse, mutect2, varscan2
- KCNH4 | c.1333G>A p.V445M | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52921554; called by muse, mutect2, varscan2
- LAIR1 | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100479553; called by muse, mutect2
- MACO1 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV65478644; called by muse, mutect2, varscan2
- MAEL | c.1162G>A p.V388I | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.044); catalogued as rs141476246, COSV63304933; called by muse, mutect2, varscan2
- MAGEC2 | c.868C>G p.P290A | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.816); catalogued as COSV56001843, COSV99910065; called by muse, mutect2, varscan2
- MAP1LC3C | c.298A>T p.T100S | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.348); catalogued as COSV61804168; called by muse, mutect2, varscan2
- MRPL15 | c.790C>G p.Q264E | Missense Mutation (SNP) | VAF 36/183 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as COSV52638973; called by muse, mutect2, varscan2
- NAT10 | c.2321G>T p.R774L | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57664597, COSV57666626; called by muse, mutect2, varscan2
- NIN | c.1285C>T p.R429* | Nonsense Mutation (SNP) | VAF 53/284 reads (19%) | catalogued as rs1566829394, COSV55408940; called by muse, mutect2, varscan2
- NPR2 | c.227C>G p.S76C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs1289231317, COSV61315080; called by muse, mutect2, varscan2
- NRXN3 | c.1768G>A p.D590N (on ENST00000557594 / NM_001272020.2; = p.D1014N on NM_004796.6) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); catalogued as COSV55322674; called by muse, mutect2, varscan2
- OXR1 | c.479T>G p.V160G (on ENST00000442977 / NM_001198532.1; = p.V159G on NM_018002.3) | Missense Mutation (SNP) | VAF 114/540 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.063); catalogued as COSV56337546; called by muse, mutect2, varscan2
- PCDHA7 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.895); catalogued as rs782612363, COSV100971531, COSV65348126; called by muse, mutect2, varscan2
- PCDHGA5 | c.2030G>A p.S677N | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.011); catalogued as rs1258181913, COSV54048191; called by muse, mutect2, varscan2
- PLSCR2 | c.578A>C p.Y193S (on ENST00000497985 / NM_001199978.1; = p.Y120S on NM_020359.2) | Missense Mutation (SNP) | VAF 235/286 reads (82%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV60865131; called by muse, mutect2, varscan2
- PPFIA1 | c.2567G>A p.R856H | Missense Mutation (SNP) | VAF 37/347 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as rs1258438687, COSV54138584, COSV54139873; called by muse, mutect2, varscan2
- PXDNL | c.1478C>T p.S493L | Missense Mutation (SNP) | VAF 57/151 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.105); catalogued as rs752274536, COSV62497910; called by muse, mutect2, varscan2
- RAE1 | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 47/347 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as COSV64799113; called by muse, mutect2, varscan2
- RDM1 | c.658G>T p.V220F | Missense Mutation (SNP) | VAF 58/457 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1229922102; called by muse, mutect2, varscan2
- RIC8A | c.1000G>C p.V334L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV57344496; called by muse, mutect2, varscan2
- RND1 | c.651C>G p.I217M | Missense Mutation (SNP) | VAF 55/240 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.06); catalogued as COSV59046269; called by muse, mutect2, varscan2
- RYR2 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 65/120 reads (54%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.833); catalogued as rs1023176208, COSV63718941; called by muse, mutect2, varscan2
- SCN10A | c.1674C>A p.S558R | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.189); catalogued as COSV71862788; called by muse, mutect2, varscan2
- SGK2 | c.187T>C p.S63P | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as rs1476667216, COSV58315541; called by muse, mutect2, varscan2
- TANC1 | c.4037G>A p.R1346Q | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs201847551; called by muse, mutect2, varscan2
- TEX14 | c.908G>A p.R303Q (on ENST00000240361 / NM_001201457.2; = p.R297Q on NM_031272.5) | Missense Mutation (SNP) | VAF 64/86 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs773123909, COSV53628029; called by muse, mutect2, varscan2
- TTLL4 | c.2165C>T p.P722L | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51439933; called by muse, mutect2, varscan2
- ZNF778 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 69/265 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757188170, COSV60603098; called by muse, mutect2, varscan2
- ZPLD1 | c.301T>G p.L101V (on ENST00000466937 / NM_001329788.1; = p.L117V on NM_175056.2) | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.772); catalogued as COSV60356525; called by muse, mutect2, varscan2
- GATA3 | c.1226dup p.S410Qfs*97 | Frame Shift Ins (INS) | VAF 9/60 reads (15%) | called by mutect2, pindel, varscan2
- GLYR1 | c.981_988delinsA p.F328Afs*45 | Frame Shift Del (DEL) | VAF 15/42 reads (36%) | called by pindel, varscan2*
- CFAP77 | c.621G>A p.G207= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV58017715; called by muse, mutect2, varscan2
- CFHR5 | c.1029G>A p.K343= | Silent (SNP) | VAF 16/111 reads (14%) | catalogued as rs555221057, COSV56829815; called by muse, mutect2, varscan2
- CNGA1 | c.1813C>T p.L605= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV62057301; called by muse, mutect2, varscan2
- F7 | c.729C>T p.I243= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as rs746792884, COSV60648459; called by muse, mutect2, varscan2
- HOXA1 | c.189G>A p.S63= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV99761117; called by muse, mutect2
- IPPK | c.1413C>T p.N471= | Silent (SNP) | VAF 42/225 reads (19%) | catalogued as rs112162638, COSV55332969, COSV99845546; called by muse, mutect2, varscan2
- IQSEC1 | c.1545G>T p.S515= | Silent (SNP) | VAF 42/64 reads (66%) | catalogued as rs543348361, COSV56225541, COSV56230405; called by muse, mutect2, varscan2
- ITGAD | c.1758G>A p.A586= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs773510109, COSV66760638; called by muse, mutect2, varscan2
- NLRP9 | c.1359C>T p.A453= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as rs746903877, COSV60468466; called by muse, mutect2, varscan2
- OGG1 | c.111G>C p.L37= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs1459287882, COSV57355433; called by muse, mutect2, varscan2
- PGAP2 | c.351C>T p.F117= (on ENST00000463452 / NM_001346398.2; = p.F178= on NM_014489.4) | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs1222798465, COSV53467933; called by muse, mutect2, varscan2
- RAPGEF6 | c.3936C>T p.H1312= | Silent (SNP) | VAF 87/152 reads (57%) | catalogued as rs756669537, COSV57256451; called by muse, mutect2, varscan2
- SCN2A | c.5316C>A p.I1772= | Silent (SNP) | VAF 43/86 reads (50%) | catalogued as COSV51837702, COSV51857559; called by muse, mutect2, varscan2
- SHOX | c.153G>A p.T51= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV61862557; called by muse, mutect2, varscan2
- TNFSF10 | c.687T>C p.S229= | Silent (SNP) | VAF 167/1127 reads (15%) | catalogued as COSV53844802; called by muse, mutect2, varscan2
- UQCRHL | c.105G>A p.E35= | Silent (SNP) | VAF 62/252 reads (25%) | catalogued as rs777650955; called by muse, mutect2, varscan2
